Surgical pathology report (de-identified scan), TCGA case TCGA-FG-A6J3, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-A6J3-01A (Primary Tumor).

[page 1 of 6]
Results

Surgical Pathology Exam (Order [REDACTED])

Result Information

Abnormality

Status

Final result ([REDACTED])

Priority
Routine

Source

Entry Date

Result Narrative

CASE: [REDACTED]

PATIENT: [REDACTED]

Clinical History: None Given

Pre-Operative Diagnoses: Brain Tumor

Post-Operative Diagnosis: Same

Specimen(s) Submitted: A. Brain Tumor F/S; B. Brain Tumor- Fresh

CPT Code(s) 88307 X 2; 88333 X 1; 88342 X 2

FINAL DIAGNOSIS:

A. Brain tumor, right frontal, biopsy:
- Anaplastic astrocytoma, WHO grade III.

B. Brain tumor, right frontal, craniotomy and resection:
- Anaplastic astrocytoma, WHO grade III.
- See comment and synoptic report.

Comment: Sections show cerebral cortex and underlying white matter with involvement by a diffusely infiltrative neoplasm. The tumor is composed of cells with angulated to irregular nuclei with moderate to marked nuclear pleomorphism. The tumor cells have a fibrillar to spindled cytoplasm and areas with a gemistocytic appearance. Occasional multinucleated tumor cells are seen. Scattered mitoses are identified. No necrosis or vascular proliferation is identified. The Ki-67 labeling index is variable, but high with areas of approximately 25%. The tumor cells are positive for mutant IDH-1 by immunohistochemistry. The histological features are consistent with an anaplastic astrocytoma, WHO grade III. The cellularity, atypia, and elevated Ki-67 labeling index are concerning for progression to a grade IV, but no necrosis or vascular proliferation is seen.

This case was prospectively reviewed within the department.

Portions of the tumor have been sent for MGMT gene methylation analysis by PCR and 1p 19q chromosomal losses by FISH. The results will be given in an addendum to this report.

SYNOPTIC REPORTSpecimen Type/Procedure:
Resection.

Specimen Handling:

Squash/smear/touch preparation.

Unfrozen for routine permanent paraffin sections.

Laterality:

Not specified.

Tumor Site:

Right frontal lobe.

Histologic Type and Grade:

Astrocytoma, anaplastic.

Histologic Grade (WHO histologic grade):

WHO grade III.

ICD O-3

Astrocytoma, grade III 9401/3

C&F

Site: Brain, supratentorial NOS

C71.0

path.

② Brain, frontal lobe

C71.1

JAD 10/10/13

[page 2 of 6]
88333

Frozen Section Diagnosis:

A. Brain tumor (SMA):

- Infiltrating high grade glioma.

(17 minutes)

Gross Description:

A. Received fresh for frozen section diagnosis, labeled with patient's name, " " and "brain tumor," is a 0.6 x 0.3 x 0.1 cm aggregate of irregular pink-white soft tissue fragments which are entirely submitted in cassette A1.

B. Received fresh, labeled with the patient's name, " " and "brain tumor," are 2 pieces of soft, partially fragmented gray tan tissue consistent with brain tissue, 16.1 g in aggregate and 2.1 x 1.5 x 0.4 cm and 5.1 x 3.5 x up to 1.7 cm. The cut surface is gray-tan to pink with a loss of delineation between gray and white matter in approximately 40% of the larger piece of tissue. Representative sections (to include approximately 45% of the specimen) are submitted in cassettes as follows:

B1 and B2: Smaller piece step-sectioned.

B3-B10: Representative larger piece of tissue.

Microscopic Description:

11 HE and 2 immunohistochemical (IDH-1 and semiquantitative Ki-67) stained slides were examined with working controls.

I have reviewed all diagnostic slides and have edited the gross and/or microscopic portion of this report as part of my pathologic assessment and final diagnosis.

Some tests use analyte-specific reagents (ASRs). These tests were developed and their performance characteristics determined by . They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. Listed are all ASRs used at IHC: CMV, EBV, HSV, PIN4, AE1/3/CAM 5.2, p504s, adenovirus. Probes consist of EBER, kappa, lambda, HPV family 6, HPV family 16, SIS HER2/neu.

The pathologist signing this report is located at

Pathologist

Electronically signed

Lab and Collection

Surgical Pathology Exam on

Authorizing Provider Information

Name:

Fax:

Phone:

Pager:

Status of Other Orders

Order

Lab Status

Result Date

Provider Status

[page 3 of 6]
CBC	Abnormal	Final result		Ordered
Protime-INR		Final result		Ordered
APTT, No Anticoagulant	Abnormal	Final result		Ordered
Basic metabolic panel	Abnormal	Final result		Ordered
POC HCG Qualitative, Urine		Final result		Ordered
ABO/Rh		Final result		Ordered
Antibody screen		Final result		Ordered
Renal Function Panel w/EGFR	Abnormal	Final result		Ordered
CBC	Abnormal	Final result		Ordered
MRI Head W WO contrast		Final result		Ordered

Standing	Remaining	Last Release
CBC	0 of 1	
Protime-INR	0 of 1	
APTT, No Anticoagulant	0 of 1	
Basic metabolic panel	0 of 1	
POC HCG Qualitative, Urine	0 of 1	
ABO/Rh	0 of 1	
Antibody screen	0 of 1	
Renal Function Panel w/EGFR	0 of 1	
CBC	0 of 1	
MRI Head W WO contrast	0 of 1	
Surgical Pathology Exam	0 of 1	

Surgical Pathology Exam (Order

Pathology and Cytology

Authorizing

Date

Released

By

Department

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time

Order Details

Frequency	Duration	Priority	Order Class
Once	1 occurrence	Routine	Normal

Reprint Requisition

Surgical Pathology Exam (Order#

Collection Information

Collection Date	Collection Time	Resolving Agency

Order Provider Info

	Office phone	Pager/beeper	E-mail
Ordering User			
Authorizing Provider			
Attending Provider			

[page 4 of 6]
Order-Level Documents:

There are no order-level documents.

Entry Date

Result Narrative

CASE:

PATIENT:

Clinical History: None Given

Pre-Operative Diagnoses: Brain Tumor

Post-Operative Diagnosis: Same

Specimen(s) Submitted: A. Brain Tumor F/S; B. Brain Tumor- Fresh

CPT Code(s) 88307 X 2; 88333 X 1; 88342 X 2

FINAL DIAGNOSIS:

A. Brain tumor, right frontal, biopsy:
- Anaplastic astrocytoma, WHO grade III.

B. Brain tumor, right frontal, craniotomy and resection:
- Anaplastic astrocytoma, WHO grade III.
- See comment and synoptic report.

Comment: Sections show cerebral cortex and underlying white matter with involvement by a diffusely infiltrative neoplasm. The tumor is composed of cells with angulated to irregular nuclei with moderate to marked nuclear pleomorphism. The tumor cells have a fibrillar to spindled cytoplasm and areas with a gemistocytic appearance. Occasional multinucleated tumor cells are seen. Scattered mitoses are identified. No necrosis or vascular proliferation is identified. The Ki-67 labeling index is variable, but high with areas of approximately 25%. The tumor cells are positive for mutant IDH-1 by immunohistochemistry. The histological features are consistent with an anaplastic astrocytoma, WHO grade III. The cellularity, atypia, and elevated Ki-67 labeling index are concerning for progression to a grade IV, but no necrosis or vascular proliferation is seen.

This case was prospectively reviewed within the department.

Portions of the tumor have been sent for MGMT gene methylation analysis by PCR and 1p 19q chromosomal losses by FISH. The results will be given in an addendum to this report.

SYNOPTIC REPORT

Specimen Type/Procedure:

Resection.

Specimen Handling:

Squash/smear/touch preparation.

Unfrozen for routine permanent paraffin sections.

Laterality:

Not specified.

Tumor Site:

Right frontal lobe.

Histologic Type and Grade:

Astrocytoma, anaplastic.

Histologic Grade (WHO histologic grade):

WHO grade III.

[page 5 of 6]
Frozen Section Diagnosis:

A. Brain tumor (SMA):

- Infiltrating high grade glioma.

(17 minutes)

Gross Description:

A. Received fresh for frozen section diagnosis, labeled with patient's name, " " and "brain tumor," is a 0.6 x 0.3 x 0.1 cm aggregate of irregular pink-white soft tissue fragments which are entirely submitted in cassette

A1.

B. Received fresh, labeled with the patient's name, " " and "brain tumor," are 2 pieces of soft, partially fragmented gray-tan tissue consistent with brain tissue, 16.1 g in aggregate and 2.1 x 1.5 x 0.4 cm and 5.1 x 3.5 x up to 1.7 cm. The cut surface is gray-tan to pink with a loss of delineation between gray and white matter in approximately 40% of the larger piece of tissue. Representative sections (to include approximately 45% of the specimen) are submitted in cassettes " " as follows:

B1 and B2: Smaller piece step-sectioned.

B3-B10: Representative larger piece of tissue.

Microscopic Description:

11 HE and 2 immunohistochemical (IDH-1 and semiquantitative Ki-67) stained slides were examined with working controls.

I have reviewed all diagnostic slides and have edited the gross and/or microscopic portion of this report as part of my pathologic assessment and final diagnosis.

Some tests use analyte-specific reagents (ASRs). These tests were developed and their performance characteristics determined by

They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. Listed are all ASRs used at IHC: CMV, EBV, HSV, PIN4, AE1/3/CAM 5.2, p504s, adenovirus. Probes consist of EBER, kappa, lambda, HPV family 6, HPV family 16, SIS HER2/

The pathologist signing this report is located at " "

Pathologist

Electronically signed " "

Lab and Collection

Surgical Pathology Exam on " "

Additional Information

Specimen ID

Bill Type

Client ID

Additional Information

[page 6 of 6]
Specimen Date Taken Specimen Time Taken Specimen Received Date Specimen Received Time Result Date Result Time

Source: NCI Genomic Data Commons file 2d30de7c-4b4c-49f1-88f4-f1fad86b9aea (TCGA-FG-A6J3.480EE630-15DD-4346-84FF-B96E973E6583.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).